Somatic mutation profile of tumor specimen ALCH-B4SP-TTP1-A (aliquot ALCH-B4SP-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4SP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.7 years (18,519 days).
Specimen ALCH-B4SP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1bd8ab1-3100-4412-86a5-d4243013dbc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4SP-NB1-A (Blood Derived Normal), aliquot ALCH-B4SP-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/777ca77a-2b0f-41dc-859f-c2f8904e3e80

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH17 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs369140843; called by mutect2, varscan2
- HTATSF1 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs369883390; called by muse, mutect2, varscan2
- KRT72 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs1426542239, COSV53375350; called by muse, mutect2
- LOXHD1 | c.4825G>A p.D1609N | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.163); catalogued as rs1275751728, COSV56063616; called by muse, mutect2
- MAGEA10 | c.855G>C p.Q285H | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV54885029; called by muse, mutect2, varscan2
- RASAL2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1324783543; called by muse, mutect2
- TRMT10B | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771763100; called by muse, mutect2
- CEP78 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- DCHS1 | c.6314G>A p.S2105N | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCGBP | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- IPO8 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- MYH3 | c.3336G>T p.L1112F | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- TMPRSS11D | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2
- FLNA | c.60C>T p.G20= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs1557180245; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPHLN1 | c.675T>A p.T225= | Silent (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- VPS51 | c.741C>T p.G247= | Silent (SNP) | VAF 8/183 reads (4%) | catalogued as rs1209698789, COSV54207402; called by muse, mutect2
- ZFX | c.1419C>T p.N473= | Silent (SNP) | VAF 103/394 reads (26%) | catalogued as COSV58448313; called by muse, mutect2, varscan2
